Somatic mutation profile of cancer-model specimen HCM-STAN-0848-C20-85A (3D Organoid, passage 6; aliquot HCM-STAN-0848-C20-85A-01D-A882-36), derived from the primary tumor of HCMI case HCM-STAN-0848-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2.
Specimen HCM-STAN-0848-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 229a0a22-895b-4a65-bd13-3532c7874519.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0848-C20-11A (Solid Tissue Normal), aliquot HCM-STAN-0848-C20-11A-11D-A882-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f062aad-81cf-4315-a63c-f6f1c985166b

The open-access MAF lists 112 somatic variants for this specimen: 83 protein-altering or splice-affecting, 25 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 25, Nonsense Mutation 5, In Frame Del 2, Frame Shift Del 2, 5'Flank 1, RNA 1, Frame Shift Ins 1, Intron 1, Nonstop Mutation 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 148/300 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 228/312 reads (73%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AADAT | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV61786973; called by muse, mutect2, varscan2
- ABHD17A | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 82/678 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs747896893; called by muse, varscan2
- ARHGAP31 | c.3127G>A p.G1043R | Missense Mutation (SNP) | VAF 225/776 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs1263839755; called by muse, mutect2, varscan2
- ASB4 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 150/327 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as COSV57508202; called by muse, mutect2, varscan2
- BDP1 | c.5497C>G p.H1833D | Missense Mutation (SNP) | VAF 260/734 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV62435071; called by muse, mutect2, varscan2
- BNIP5 | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.741); catalogued as rs376079446; called by muse, mutect2
- C16orf71 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 180/491 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs781592659; called by muse, mutect2, varscan2
- CIAO3 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 283/583 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs752289658; called by muse, varscan2
- ERBB2 | c.2632C>T p.H878Y | Missense Mutation (SNP) | VAF 179/332 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54066178; called by muse, mutect2, varscan2
- FANCL | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 165/338 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52074779; called by muse, mutect2, varscan2
- FRYL | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as rs778541984; called by muse, mutect2
- FSIP2 | c.17248G>A p.E5750K | Missense Mutation (SNP) | VAF 132/311 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1353615587, COSV58077311; called by muse, mutect2
- ITGA1 | c.3429G>T p.W1143C | Missense Mutation (SNP) | VAF 39/500 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs762977481; called by muse, mutect2
- LRCH2 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 230/232 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs1027988478, COSV57747256; called by muse, mutect2, varscan2
- MIPEP | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 170/874 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs546719717, COSV66301531; called by muse, mutect2, varscan2
- MMACHC | c.395_397del p.R132del | In Frame Del (DEL) | VAF 34/334 reads (10%) | catalogued as rs1455190457; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- MTOR | c.1499A>T p.D500V | Missense Mutation (SNP) | VAF 170/356 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV63872465; called by muse, mutect2, varscan2
- MYO18B | c.5684G>A p.R1895H | Missense Mutation (SNP) | VAF 148/398 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs370592345, COSV100125144; called by muse, mutect2, varscan2
- NEUROD4 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs760713144; called by muse, mutect2, varscan2
- OR1N1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 193/415 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs767738634, COSV59196059; called by muse, mutect2, varscan2
- OR2V1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 161/642 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs762779171, COSV61459392; called by muse, mutect2, varscan2
- PKHD1 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 226/456 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs186202437; called by muse, mutect2, varscan2
- PLCL2 | c.2422G>A p.A808T (on ENST00000615277 / NM_001144382.2; = p.A682T on NM_015184.5) | Missense Mutation (SNP) | VAF 147/299 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs148180373; called by muse, mutect2, varscan2
- RGS12 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 227/479 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359287871; called by muse, mutect2, varscan2
- ROR2 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 251/513 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980417569; called by muse, mutect2, varscan2
- RPL3L | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 260/545 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs370640499; called by muse, varscan2
- SHOC2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 116/261 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV54624190; called by muse, mutect2, varscan2
- SLC5A4 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 139/283 reads (49%) | catalogued as rs754133867, COSV56670664; called by muse, mutect2, varscan2
- SORCS3 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 66/808 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100865358; called by muse, mutect2
- SULT2A1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 148/310 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs529798485; called by muse, mutect2, varscan2
- TDRD6 | c.5575T>G p.S1859A | Missense Mutation (SNP) | VAF 11/362 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as COSV60175148; called by muse, mutect2
- TOPAZ1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 129/286 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs376633336; called by muse, mutect2, varscan2
- TTC28 | c.2821G>C p.E941Q | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV67418093; called by muse, mutect2
- USH2A | c.2072G>T p.C691F | Missense Mutation (SNP) | VAF 213/457 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM095918; called by muse, mutect2, varscan2
- VN1R1 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 133/364 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.155); catalogued as COSV100320601; called by muse, mutect2, varscan2
- WASF3 | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 198/1007 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1179470680, COSV58967219; called by muse, mutect2, varscan2
- WDFY3 | c.7156C>T p.R2386* | Nonsense Mutation (SNP) | VAF 221/433 reads (51%) | catalogued as rs989023195, COSV99883382; called by muse, mutect2, varscan2
- ZNF596 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 117/119 reads (98%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV100261862; called by muse, mutect2, varscan2
- ACAD10 | c.1455A>T p.E485D | Missense Mutation (SNP) | VAF 221/416 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- ADGRG5 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 91/307 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ANK2 | c.2734_2754del p.H912_D918del | In Frame Del (DEL) | VAF 69/252 reads (27%) | called by mutect2, pindel, varscan2
- BORA | c.1153G>C p.G385R (on ENST00000613797; = p.G310R on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 224/587 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BPTF | c.4340C>T p.T1447I | Missense Mutation (SNP) | VAF 129/355 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTBD18 | c.1834C>T p.H612Y | Missense Mutation (SNP) | VAF 137/330 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTNL3 | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 369/606 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CADM2 | c.442A>T p.T148S (on ENST00000407528 / NM_001167674.2; = p.T150S on NM_153184.4) | Missense Mutation (SNP) | VAF 25/526 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.077); called by muse, mutect2
- CDX2 | c.521A>G p.Q174R | Missense Mutation (SNP) | VAF 54/1186 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.73); called by muse, mutect2
- CLP1 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 259/472 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DEFB124 | c.106A>C p.T36P | Missense Mutation (SNP) | VAF 145/636 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DNER | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 110/321 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by mutect2, varscan2
- EHBP1L1 | c.3938G>C p.G1313A | Missense Mutation (SNP) | VAF 151/408 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ENPP1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 92/173 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- EXPH5 | c.2420C>T p.T807I | Missense Mutation (SNP) | VAF 159/385 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- FKBP7 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FRMPD1 | c.3274G>C p.G1092R | Missense Mutation (SNP) | VAF 120/479 reads (25%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- GPBP1 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 22/610 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.385); called by muse, mutect2
- HAUS2 | c.530T>A p.V177E | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- HPS1 | c.735C>G p.Y245* | Nonsense Mutation (SNP) | VAF 91/283 reads (32%) | called by muse, mutect2, varscan2
- IFT88 | c.2389T>A p.Y797N (on ENST00000319980 / NM_001318493.2; = p.Y788N on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 184/557 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRTAP15-1 | c.292G>C p.G98R | Missense Mutation (SNP) | VAF 202/443 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- LRRC72 | c.568A>T p.K190* | Nonsense Mutation (SNP) | VAF 146/284 reads (51%) | called by muse, mutect2, varscan2
- MBD5 | c.786T>A p.N262K | Missense Mutation (SNP) | VAF 154/309 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- MED16 | c.1610C>A p.S537* | Nonsense Mutation (SNP) | VAF 190/499 reads (38%) | called by muse, mutect2, varscan2
- MFSD14B | c.219_220insG p.F74Vfs*32 | Frame Shift Ins (INS) | VAF 103/278 reads (37%) | called by mutect2, pindel, varscan2
- MGAM2 | c.2462T>G p.L821R | Missense Mutation (SNP) | VAF 103/215 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MMAA | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 155/355 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NCOA2 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 160/331 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEUROD4 | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NUMA1 | c.1691del p.E564Gfs*4 | Frame Shift Del (DEL) | VAF 183/622 reads (29%) | called by mutect2, pindel, varscan2
- OR8H1 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 124/206 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0); called by mutect2, varscan2
- OTUD7A | c.2530G>A p.A844T (on ENST00000307050 / NM_001382637.1; = p.A837T on NM_130901.3) | Missense Mutation (SNP) | VAF 320/324 reads (99%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.024); called by muse, varscan2
- PRKCZ | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 237/510 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RANBP2 | c.2025A>C p.K675N | Missense Mutation (SNP) | VAF 99/262 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, varscan2
- RIPK1 | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLX1A | c.583-1G>C p.X195_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | called by mutect2, varscan2
- SSC5D | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 137/462 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STRA8 | c.650C>T p.P217L (on ENST00000275764; = p.P195L on NM_182489.2) | Missense Mutation (SNP) | VAF 322/674 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNE1 | c.21243del p.I7081Mfs*8 (on ENST00000367255 / NM_182961.4; = p.I7010Mfs*8 on NM_033071.3) | Frame Shift Del (DEL) | VAF 96/274 reads (35%) | called by mutect2, pindel, varscan2
- TRAF6 | c.1240A>G p.M414V | Missense Mutation (SNP) | VAF 166/352 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- ZNF18 | c.691A>C p.T231P | Missense Mutation (SNP) | VAF 105/140 reads (75%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- ZNF202 | c.1945T>G p.*649Eext*49 | Nonstop Mutation (SNP) | VAF 111/268 reads (41%) | called by muse, mutect2
- APCDD1L | c.1011C>T p.T337= | Silent (SNP) | VAF 54/982 reads (5%) | catalogued as rs1568731975, COSV64487714; called by muse, mutect2
- ATP1A3 | c.669C>T p.G223= (on ENST00000545399 / NM_001256214.2; = p.G210= on NM_152296.5) | Silent (SNP) | VAF 141/270 reads (52%) | catalogued as rs199906040; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1S | c.639C>T p.I213= | Silent (SNP) | VAF 163/350 reads (47%) | catalogued as rs1229722414, COSV62938408; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRNA7 | c.129C>G p.P43= | Silent (SNP) | VAF 26/512 reads (5%) | catalogued as rs769072651; called by muse, mutect2
- CRAMP1 | c.981G>A p.P327= | Silent (SNP) | VAF 238/482 reads (49%) | catalogued as rs778796282; called by muse, mutect2, varscan2
- CSMD1 | c.8193G>A p.T2731= (on ENST00000520002; = p.T2730= on NM_033225.6) | Silent (SNP) | VAF 111/111 reads (100%) | catalogued as rs757939119, COSV59377764; called by muse, mutect2, varscan2
- CTSE | c.243T>G p.T81= | Silent (SNP) | VAF 141/308 reads (46%) | called by muse, mutect2, varscan2
- CYLD | c.1881G>A p.K627= | Silent (SNP) | VAF 82/214 reads (38%) | called by muse, varscan2
- DNAH1 | c.4944G>A p.Q1648= | Silent (SNP) | VAF 152/414 reads (37%) | catalogued as rs1187570116; called by muse, mutect2, varscan2
- DNAH5 | c.2868C>T p.R956= | Silent (SNP) | VAF 374/586 reads (64%) | catalogued as rs767246326, COSV54204914; called by muse, mutect2, varscan2
- EIF2A | c.510T>C p.I170= | Silent (SNP) | VAF 79/346 reads (23%) | called by muse, mutect2, varscan2
- EZH2 | c.1131T>C p.D377= (on ENST00000460911 / NM_001203247.2; = p.D382= on NM_004456.5) | Silent (SNP) | VAF 50/588 reads (9%) | catalogued as COSV100235434; called by muse, mutect2
- FLT1 | c.2610C>T p.S870= | Silent (SNP) | VAF 155/802 reads (19%) | called by muse, mutect2, varscan2
- FLT4 | c.3474G>A p.A1158= | Silent (SNP) | VAF 464/706 reads (66%) | catalogued as rs887043029; called by muse, varscan2
- GALNT9 | c.942C>T p.D314= | Silent (SNP) | VAF 160/512 reads (31%) | catalogued as rs782318389, COSV61100613; called by muse, mutect2, varscan2
- HTR1B | c.276G>C p.A92= | Silent (SNP) | VAF 192/465 reads (41%) | called by muse, mutect2, varscan2
- MBD3L2 | c.456G>A p.G152= | Silent (SNP) | VAF 52/240 reads (22%) | catalogued as rs1322149274; called by mutect2, varscan2
- NLGN4Y | c.2247C>T p.H749= | Silent (SNP) | VAF 473/473 reads (100%) | called by muse, mutect2, varscan2
- NPHS1 | c.117A>G p.E39= | Silent (SNP) | VAF 257/550 reads (47%) | called by muse, mutect2, varscan2
- NSD1 | c.2484T>G p.S828= | Silent (SNP) | VAF 44/508 reads (9%) | called by muse, mutect2
- PCDHB13 | c.1665C>T p.N555= | Silent (SNP) | VAF 437/1499 reads (29%) | catalogued as rs377408073; called by muse, mutect2, varscan2
- PDZRN3 | c.2394G>A p.T798= | Silent (SNP) | VAF 50/650 reads (8%) | catalogued as rs373980614; called by muse, mutect2
- RALGAPA1 | c.1557C>T p.N519= | Silent (SNP) | VAF 86/145 reads (59%) | called by muse, mutect2, varscan2
- ZFP92 | c.612C>T p.G204= | Silent (SNP) | VAF 48/1027 reads (5%) | catalogued as rs782813653, COSV100100138; called by muse, mutect2
- ZPBP2 | c.498G>A p.V166= (on ENST00000348931 / NM_199321.3; = p.V144= on NM_198844.3) | Silent (SNP) | VAF 112/344 reads (33%) | catalogued as rs751383469, COSV62375656; called by muse, mutect2
- AC244258.1 | n.461C>A | RNA (SNP) | VAF 44/106 reads (42%) | called by mutect2, varscan2
- ARNTL | c.180-73_180-66del | Intron (DEL) | VAF 99/340 reads (29%) | called by mutect2, pindel, varscan2
- G3BP1 | chr5:151770525 G>A | 5'Flank (SNP) | VAF 351/1049 reads (33%) | called by muse, mutect2, varscan2
- ZNF875 | c.-96C>A | 5'UTR (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
